Somatic mutation profile of tumor specimen MMRF_2363_2_BM_CD138pos (aliquot MMRF_2363_2_BM_CD138pos_T3_KHS5U_K14007) from MMRF case MMRF_2363, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.0 years (19,353 days).
Specimen MMRF_2363_2_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27d33eb3-ee69-4669-87dd-62bf34abb2f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2363_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2363_1_PB_Whole_C3_KHS5U_K14006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5625dc5e-3d27-4caf-a990-1e0635b70bce

The open-access MAF lists 149 somatic variants for this specimen: 56 protein-altering or splice-affecting, 25 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 39, Silent 25, Intron 21, Nonsense Mutation 6, RNA 3, 5'UTR 3, 3'Flank 2, Translation Start Site 1, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX15 | c.338-4C>T | Splice Region (SNP) | VAF 28/256 reads (11%) | catalogued as rs775234808; called by muse, mutect2, varscan2
- CHD2 | c.2201C>T p.T734I | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs866022844; called by muse, mutect2
- CSMD3 | c.8699C>T p.S2900L (on ENST00000297405 / NM_001363185.1; = p.S2731L on NM_052900.3) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.378); catalogued as rs1203094336; called by muse, mutect2, varscan2
- FGA | c.2340C>A p.H780Q | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs755826305, COSV57395433; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as rs1443373848; called by muse, mutect2, varscan2
- KCNH5 | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs757865714; called by muse, mutect2, varscan2
- KLF17 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs758007346; called by muse, mutect2
- KMT2C | c.11539A>G p.K3847E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51360845; called by muse, mutect2, varscan2
- MPO | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.428); catalogued as COSV56563943; called by muse, mutect2, varscan2
- MUC16 | c.10915G>T p.G3639* | Nonsense Mutation (SNP) | VAF 7/161 reads (4%) | catalogued as rs1176748970; called by muse, mutect2
- NFKB2 | c.1227del p.T410Rfs*72 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as COSV50046739, COSV50049142; called by mutect2, pindel, varscan2
- PCDHA3 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV63538638; called by mutect2, varscan2
- PHOSPHO2 | c.118C>G p.R40G | Missense Mutation (SNP) | VAF 150/286 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs750165487; called by muse, mutect2, varscan2
- PNPLA7 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs1284342134; called by muse, mutect2, varscan2
- PRB4 | c.289G>T p.G97* | Nonsense Mutation (SNP) | VAF 29/98 reads (30%) | catalogued as COSV54398968; called by muse, varscan2
- RPL10 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50010499; called by muse, mutect2, varscan2
- SIDT1 | c.1864G>T p.G622* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV53498064; called by muse, mutect2
- SLC22A9 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as rs1392427185; called by muse, mutect2
- SLITRK6 | c.1693C>A p.L565I | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs373437250; called by muse, mutect2, varscan2
- ACAA2 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ADGRB1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ALDH1A1 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKRD30B | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ASTN2 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- AZIN1 | c.666+2T>G p.X222_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- BTN2A1 | c.137A>C p.N46T | Missense Mutation (SNP) | VAF 122/474 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2
- CDH9 | c.1921A>T p.K641* | Nonsense Mutation (SNP) | VAF 34/219 reads (16%) | called by muse, mutect2, varscan2
- CLPX | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CSH1 | c.556T>C p.Y186H | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CUL3 | c.1442A>G p.N481S | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CUL3 | c.1045A>G p.K349E | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ETV3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- GDAP2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- GLG1 | c.50T>A p.L17Q | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- HK2 | c.2363C>G p.S788C | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JADE3 | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- LRRC4C | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- LRRC69 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MBNL1 | c.525dup p.L176Ifs*8 | Frame Shift Ins (INS) | VAF 17/103 reads (17%) | called by mutect2, pindel, varscan2
- MROH2B | c.2994G>T p.K998N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- NCKAP5L | c.2897T>C p.L966P | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA6 | c.5765T>C p.V1922A | Missense Mutation (SNP) | VAF 81/138 reads (59%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPAT | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OBSL1 | c.5330T>C p.L1777P | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHF8 | c.2564T>C p.L855P (on ENST00000357988 / NM_001184896.1; = p.L819P on NM_015107.3) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PISD | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2
- PPP1R9A | c.2165T>A p.I722K | Missense Mutation (SNP) | VAF 5/114 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2
- PRR5L | c.571T>A p.L191M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PSME4 | c.2835G>C p.M945I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRF | c.4818G>C p.E1606D | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RILP | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SLC24A4 | c.737A>T p.K246M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC30A1 | c.611T>A p.L204* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- TSHZ1 | c.2483T>C p.V828A (on ENST00000580243 / NM_001308210.2; = p.V783A on NM_005786.6) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- XPA | c.602A>C p.E201A | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ZBTB8B | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.886); called by muse, mutect2
- BTN2A1 | c.135A>G p.E45= | Silent (SNP) | VAF 120/468 reads (26%) | called by muse, mutect2
- C9orf50 | c.612G>A p.S204= | Silent (SNP) | VAF 98/172 reads (57%) | catalogued as rs745405190, COSV65252155; called by muse, mutect2, varscan2
- CADPS | c.3951G>T p.T1317= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs368491888; called by muse, mutect2
- CIDEB | c.357C>A p.G119= | Silent (SNP) | VAF 12/404 reads (3%) | called by muse, mutect2
- COL4A2 | c.3282G>A p.G1094= | Silent (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- DNAJC13 | c.3393C>T p.Y1131= | Silent (SNP) | VAF 31/209 reads (15%) | called by muse, mutect2, varscan2
- FAM155A | c.708G>T p.S236= | Silent (SNP) | VAF 24/195 reads (12%) | catalogued as COSV65593575; called by muse, mutect2, varscan2
- FAM47C | c.2487G>A p.Q829= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- FZD7 | c.264G>T p.P88= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV53808455; called by muse, mutect2
- GRID2 | c.846G>C p.T282= | Silent (SNP) | VAF 30/644 reads (5%) | catalogued as rs773668647, COSV56168084; called by muse, mutect2
- H3C11 | c.261C>T p.S87= | Silent (SNP) | VAF 92/189 reads (49%) | catalogued as rs766354606; called by muse, mutect2, varscan2
- IGHV3-74 | c.228C>T p.S76= | Silent (SNP) | VAF 92/98 reads (94%) | catalogued as rs189760636; called by muse, varscan2
- MGAT5B | c.195C>T p.P65= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs747200948, COSV100048514, COSV56927655; called by muse, mutect2, varscan2
- OR51I1 | c.615C>T p.I205= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV66508989; called by muse, mutect2
- OR5D18 | c.843G>C p.V281= | Silent (SNP) | VAF 105/228 reads (46%) | catalogued as COSV61738947; called by muse, mutect2, varscan2
- PCDH15 | c.1818T>G p.L606= | Silent (SNP) | VAF 16/102 reads (16%) | called by mutect2, varscan2
- PKMYT1 | c.627G>A p.Q209= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV99234014; called by muse, mutect2, varscan2
- PTPRQ | c.6120T>C p.F2040= (on ENST00000616559; = p.F2007= on NM_001145026.2) | Silent (SNP) | VAF 66/128 reads (52%) | called by muse, mutect2, varscan2
- RCBTB2 | c.381T>G p.A127= | Silent (SNP) | VAF 24/150 reads (16%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3804C>T p.S1268= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1434453673; called by muse, mutect2, varscan2
- SYNE2 | c.15669C>G p.S5223= | Silent (SNP) | VAF 31/115 reads (27%) | called by muse, mutect2, varscan2
- TERT | c.2241C>G p.V747= | Silent (SNP) | VAF 47/847 reads (6%) | called by muse, mutect2
- TRIM44 | c.696C>T p.A232= | Silent (SNP) | VAF 100/225 reads (44%) | catalogued as rs757722204, COSV100194915; called by muse, mutect2, varscan2
- TTN | c.28095A>G p.K9365= (on ENST00000591111; = p.K8438= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.1368G>A p.E456= | Silent (SNP) | VAF 39/147 reads (27%) | called by muse, mutect2, varscan2
- AL645728.2 | n.189C>A | RNA (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- AL645728.2 | n.190T>C | RNA (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- ANKRD22 | c.*2326A>G | 3'UTR (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- ANKRD29 | c.*1456C>T | 3'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- ARSJ | c.*483G>T | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- ASCC3 | c.-22T>A | 5'UTR (SNP) | VAF 22/295 reads (7%) | called by muse, mutect2
- BAIAP2 | c.1535+580G>T | Intron (SNP) | VAF 73/134 reads (54%) | called by muse, mutect2
- C2CD4B | c.*214C>T | 3'UTR (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- CACNA1G | c.4422+121C>A | Intron (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- CC2D2B | c.523-67C>T | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- CHRNB3 | c.*252C>G | 3'UTR (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- CKAP2 | c.1479+161G>A | Intron (SNP) | VAF 109/234 reads (47%) | called by muse, mutect2, varscan2
- CLIP2 | c.*1280G>A | 3'UTR (SNP) | VAF 26/71 reads (37%) | catalogued as rs1009664968; called by muse, mutect2, varscan2
- CLK4 | c.161+769G>A | Intron (SNP) | VAF 23/232 reads (10%) | called by muse, mutect2, varscan2
- CPNE5 | c.*128G>C | 3'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2935921 G>A | 3'Flank (SNP) | VAF 55/109 reads (50%) | catalogued as rs1448708871; called by muse, mutect2, varscan2
- CSRNP3 | c.*4143C>T | 3'UTR (SNP) | VAF 72/163 reads (44%) | catalogued as rs923370391; called by muse, mutect2, varscan2
- DEFB127 | c.*77C>T | 3'UTR (SNP) | VAF 97/214 reads (45%) | called by muse, mutect2, varscan2
- ELK3 | c.*1146C>A | 3'UTR (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- FAM221B | c.*520C>T | 3'UTR (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- FGF5 | c.*1595C>A | 3'UTR (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- GABRA4 | c.*5478T>A | 3'UTR (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- GABRA5 | c.*798A>C | 3'UTR (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2
- GALNT2 | c.*425A>G | 3'UTR (SNP) | VAF 33/304 reads (11%) | catalogued as rs918914935; called by muse, mutect2, varscan2
- GCSAML | c.*1570del | 3'UTR (DEL) | VAF 18/41 reads (44%) | called by mutect2, varscan2
- GRHPR | c.734+254A>C | Intron (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- GRHPR | c.734+255G>T | Intron (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- GRIA4 | c.*1985C>T | 3'UTR (SNP) | VAF 28/253 reads (11%) | catalogued as rs1230891666; called by muse, mutect2, varscan2
- HLA-DQA1 | c.82+1471G>A | Intron (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1123A>G | RNA (SNP) | VAF 57/117 reads (49%) | called by muse, mutect2, varscan2
- IL4R | c.361+294C>T | Intron (SNP) | VAF 58/121 reads (48%) | called by muse, mutect2, varscan2
- JAG2 | c.*1181C>T | 3'UTR (SNP) | VAF 61/347 reads (18%) | called by muse, mutect2, varscan2
- KCNS2 | c.*1193C>T | 3'UTR (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- KREMEN1 | chr22:29146711 T>G | 3'Flank (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- LAMC1 | c.*1765G>T | 3'UTR (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- LHX9 | c.*3141C>G | 3'UTR (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- LIMCH1 | c.487-928C>A | Intron (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- MYOC | c.*118T>G | 3'UTR (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- NALCN | c.2193-5333G>A | Intron (SNP) | VAF 25/197 reads (13%) | catalogued as rs1403946398; called by muse, mutect2, varscan2
- NINL | c.3697-32C>T | Intron (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- NOP56 | c.1419+44A>C | Intron (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+10052C>G | Intron (SNP) | VAF 44/148 reads (30%) | catalogued as rs1019680842; called by muse, mutect2, varscan2
- PAPPA2 | c.2431+479A>C | Intron (SNP) | VAF 14/26 reads (54%) | called by mutect2, varscan2
- PHF8 | c.-15T>A | 5'UTR (SNP) | VAF 19/109 reads (17%) | called by muse, mutect2, varscan2
- PLEKHG7 | c.530+334_530+336del | Intron (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- PRICKLE2 | c.*4039G>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- PRSS40A | n.318-629G>C | Intron (SNP) | VAF 14/93 reads (15%) | catalogued as rs1186565803; called by muse, mutect2, varscan2
- PSD3 | c.1635-3973C>T | Intron (SNP) | VAF 99/196 reads (51%) | catalogued as rs1461125440; called by muse, mutect2, varscan2
- RNF152 | c.*2348G>T | 3'UTR (SNP) | VAF 40/162 reads (25%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*7332T>A | 3'UTR (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- TMEM154 | c.*759A>T | 3'UTR (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- TMEM199 | c.*1011T>G | 3'UTR (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- TMEM86A | c.*803C>G | 3'UTR (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2, varscan2
- TNF | c.*577G>A | 3'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs951641470; called by muse, mutect2
- TRDMT1 | c.*373G>T | 3'UTR (SNP) | VAF 31/55 reads (56%) | catalogued as rs1420211939; called by muse, mutect2, varscan2
- TTN | c.10361-5477A>T | Intron (SNP) | VAF 14/170 reads (8%) | catalogued as rs727504519; ClinVar: uncertain significance; called by muse, mutect2
- TXNRD1 | c.*1822_*1823del | 3'UTR (DEL) | VAF 4/44 reads (9%) | catalogued as rs1491407299; called by pindel, varscan2
- UBE2I | c.*288T>C | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- UGT3A2 | c.*179T>A | 3'UTR (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- USP53 | c.*749A>C | 3'UTR (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- VEGFC | c.*197T>G | 3'UTR (SNP) | VAF 62/126 reads (49%) | called by muse, mutect2, varscan2
- VTCN1 | c.33-3070C>T | Intron (SNP) | VAF 20/240 reads (8%) | catalogued as rs1239030760; called by muse, mutect2
- ZFX | c.*753T>A | 3'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- ZFX | c.*858T>A | 3'UTR (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- ZGLP1 | c.-1051G>A | 5'UTR (SNP) | VAF 42/109 reads (39%) | catalogued as rs990911285; called by muse, mutect2, varscan2
- ZNF326 | c.*57del | 3'UTR (DEL) | VAF 33/142 reads (23%) | called by mutect2, pindel, varscan2
- ZNF462 | c.*2452T>A | 3'UTR (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- ZNF726 | c.226+407C>G | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
